MMRF case MMRF_1202 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8748709a-73b9-4807-a874-4a54b6b83118

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Dead; Days to death: 921 days (2.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.8 years (21,838 days); ISS stage: II; Days to last known disease status: 921 days (2.5 years); Days to last follow up: 921 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 484 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 152 days; Days to treatment end: 484 days (1.3 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 312 days; Days to treatment end: 312 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 314 days; Days to treatment end: 314 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 697 days (1.9 years); Days to treatment end: 810 days (2.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 872 days (2.4 years); Days to treatment end: 890 days (2.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 921.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.1 mg/dL; Immunoglobulin G 56.5 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 3.06 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.78 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 29 g/L; Total Protein 10.1 g/dL; Glucose 5.5 mmol/L.
- Day 117 (ECOG 0): M Protein 1 g/dL; Immunoglobulin G 16.8 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.32 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Total Protein 6.3 g/dL; Glucose 9.52 mmol/L.
- Day 159 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.15 mg/dL; Immunoglobulin G 10.6 g/L; Beta 2 Microglobulin 1.73 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.3 g/dL; Glucose 9.57 mmol/L.
- Day 257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 5.07 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.86 g/L; Beta 2 Microglobulin 1.59 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 11.4 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 6.05 mmol/L.
- Day 362 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 7.45 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.27 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.
- Day 418 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 7.12 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.26 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.68 mmol/L.
- Day 516 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.321 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.929 mg/dL; Immunoglobulin G 6.28 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Total Protein 6.5 g/dL.
- Day 572 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.339 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.958 mg/dL; Immunoglobulin G 6.22 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 68.1 µmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL.
- Day 712 (ECOG 0): M Protein 2.2 g/dL; Immunoglobulin G 25.5 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 78.7 µmol/L.
- Day 798 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.572 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 3.94 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 31 g/L; Total Protein 5.5 g/dL; Glucose 9.13 mmol/L.
- Day 900: M Protein 9.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.139 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 99.8 mg/dL.

Other clinical attributes
- Day -13: Weight: 117 kg; Height: 173 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1202_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1202_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
- Sample MMRF_1202_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 418 days (1.1 years).
